MMRF case MMRF_1401 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b03091a4-be70-44d2-a3fe-e0eeeee4e478

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 575 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.9 years (30,263 days); ISS stage: II; Days to last known disease status: 575 days (1.6 years); Days to last follow up: 575 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 542 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 91 days; Days to treatment end: 247 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 91 days; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 261 days; Days to treatment end: 427 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 430 days (1.2 years); Days to treatment end: 500 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 575.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 2): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Immunoglobulin G 2.98 g/L; Immunoglobulin A 21.4 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 4.85 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.58 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 5.39 mmol/L.
- Day 79 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.636 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 76.3 mg/dL; Immunoglobulin G 2.35 g/L; Immunoglobulin A 11.3 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 4.97 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 7.98 mmol/L.
- Day 171 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.819 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 1.94 g/L; Immunoglobulin A 3.26 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.59 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 6.77 mmol/L.
- Day 260 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.757 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.696 mg/dL; Immunoglobulin G 2.13 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.39 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 5.61 mmol/L.
- Day 343 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 3.07 g/L; Immunoglobulin A 5.44 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.2 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.88 mmol/L.
- Day 427 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 2.39 g/L; Immunoglobulin A 16.6 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 6.11 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 1.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 10.3 mmol/L.
- Day 528 (ECOG 1): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 1.1 g/L; Immunoglobulin A 35 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 8.79 µg/mL; Hemoglobin 4.71 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.75 mmol/L; Albumin 36 g/L; Total Protein 8.9 g/dL; Glucose 7.48 mmol/L.

Other clinical attributes
- Day -11: Weight: 75 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1401_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_1401_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
- Sample MMRF_1401_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 427 days (1.2 years).
